TCGA case TCGA-E8-A416 — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/86b82345-6f4d-44fd-a9db-6f107de62f53

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Vietnam; Age at index: 51 years; Vital status: Alive.

Diagnoses (1)
1. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 51.8 years (18,932 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 952 days (2.6 years); Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Measurement unit: Centimeters; Tumor width measurement: 1.5.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant.
   Recorded as not given: adjuvant Radiation, External Beam.

Follow-up (5 entries)
- Days to follow up: 22 days; Disease response: Tumor Free.
- Days to follow up: 428 days (1.2 years); Disease response: Tumor Free.
- Days to follow up: 952 days (2.6 years); Disease response: Tumor Free.
- Imaging type: Ultrasound; Imaging anatomic site: Lymph Node; Timepoint: Preoperative.
- Disease response: Complete Response; Timepoint: Within 3 Months of Surgery.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-E8-A416-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 330 mg. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
  Slide TCGA-E8-A416-01A-01-TSA: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 65; Percent normal cells: 2; Percent necrosis: 0; Percent stromal cells: 33; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
- Sample TCGA-E8-A416-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-E8-A416-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Classical/usual; Laterality: Left lobe; Lymph nodes preop imaging: Yes; Lymph nodes examined: No; Genotypic analysis detected: No; New tumor event diagnosis indicator: No.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; I 131 radiation first treatment method: Thyroxine withdrawal; Radiation therapy xrt method prep: Patient Did Not Receive External Radiation Therapy; Clinical status within 3 mths surgery: No imaging evidence of disease; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 952 days; disease-specific survival: no event (censored), 952 days; disease-free interval: no event (censored), 952 days; progression-free interval: no event (censored), 952 days.
